Somatic mutation profile of tumor specimen TCGA-17-Z043-01A (aliquot TCGA-17-Z043-01A-01W-0746-08) from TCGA case TCGA-17-Z043, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z043-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9cc9e034-5f42-47e1-a304-3e2d2935f57a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z043-11A (Solid Tissue Normal), aliquot TCGA-17-Z043-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b500bb0-30fb-4431-bec8-2903a949a40a

The open-access MAF lists 220 somatic variants for this specimen: 157 protein-altering or splice-affecting, 57 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 136, Silent 57, Nonsense Mutation 11, Splice Site 4, Frame Shift Del 3, Intron 3, RNA 2, Frame Shift Ins 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50281488, COSV50317507; called by muse, mutect2, varscan2
- AC136428.1 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 41/252 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.97); catalogued as COSV101434980; called by muse, mutect2, varscan2
- ALK | c.779G>T p.S260I | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.691); catalogued as COSV66595041; called by muse, mutect2, varscan2
- ASB12 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62856598; called by muse, mutect2, varscan2
- ATP1A4 | c.1876C>A p.H626N | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63626045; called by muse, mutect2, varscan2
- BAZ2B | c.3301C>T p.R1101* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as COSV54275171; called by muse, mutect2, varscan2
- BEND2 | c.1130C>A p.T377K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0.012); catalogued as rs28496595, COSV101191993; called by muse, mutect2, varscan2
- CC2D2A | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); catalogued as rs772016081, COSV67504953; called by muse, mutect2, varscan2
- CCDC33 | c.1053G>T p.E351D | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as rs776598763; called by muse, mutect2, varscan2
- CCN1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs146738107; called by muse, mutect2, varscan2
- CD86 | c.824G>A p.R275Q (on ENST00000330540 / NM_175862.5; = p.R269Q on NM_006889.4) | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373228315; called by muse, mutect2, varscan2
- CSMD1 | c.9427G>A p.V3143M (on ENST00000520002; = p.V3142M on NM_033225.6) | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs530394705; called by muse, mutect2, varscan2
- DNAAF3 | c.1195G>A p.A399T (on ENST00000524407 / NM_001256715.2; = p.A446T on NM_178837.4) | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.461); catalogued as rs1333346117; called by muse, mutect2, varscan2
- DNAH3 | c.4664T>C p.M1555T | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs770767272; called by muse, mutect2, varscan2
- DOCK9 | c.5227A>G p.I1743V (on ENST00000376460 / NM_001366676.2; = p.I1744V on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.076); catalogued as rs970425130; called by muse, mutect2, varscan2
- EPHA6 | c.2804G>T p.R935M | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67590470; called by muse, mutect2, varscan2
- EPN1 | c.1221T>G p.F407L (on ENST00000270460 / NM_001321263.1; = p.F381L on NM_013333.3) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs944327289; called by muse, mutect2, varscan2
- ERICH3 | c.1184A>G p.Y395C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188264159; called by muse, mutect2, varscan2
- FCRL1 | c.684C>A p.H228Q | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1193355145; called by muse, mutect2, varscan2
- FOXL1 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.886); catalogued as rs750324359, COSV100206321; called by muse, mutect2, varscan2
- HTR1E | c.961G>T p.V321L | Missense Mutation (SNP) | VAF 79/328 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.018); catalogued as rs764082795, COSV100541334; called by muse, mutect2, varscan2
- HTR5A | c.1004C>A p.P335H | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55287315; called by muse, mutect2, varscan2
- IFNA16 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as rs1183431159; called by muse, mutect2, varscan2
- ITPR2 | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as rs775062499, COSV104430522; called by muse, mutect2, varscan2
- KIAA1614 | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs762991763, COSV62553534; called by muse, mutect2, varscan2
- LRP1B | c.10070G>A p.C3357Y | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67184087; called by muse, mutect2, varscan2
- LRRC7 | c.1135-1G>C p.X379_splice (on ENST00000651989 / NM_001370785.2; = p.X346_splice on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 6/46 reads (13%) | catalogued as COSV50456230; called by muse, mutect2
- MIA3 | c.3231G>T p.Q1077H | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as rs781214860; called by muse, mutect2, varscan2
- MYO1D | c.2839G>T p.G947* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as rs1200863208, COSV59015494; called by muse, mutect2, varscan2
- NLRP6 | c.2106-1G>T p.X702_splice | Splice Site (SNP) | VAF 10/19 reads (53%) | catalogued as rs1329304026; called by muse, mutect2, varscan2
- OPN3 | c.458G>T p.W153L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs1418375671; called by muse, mutect2, varscan2
- OR11L1 | c.614C>A p.A205D | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as rs1233189668, COSV63315639; called by muse, mutect2, varscan2
- OR5A2 | c.458G>C p.G153A | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV57390400; called by muse, mutect2, varscan2
- OR5L2 | c.512C>A p.S171Y | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV101004346; called by muse, mutect2, varscan2
- PLCL2 | c.672G>C p.E224D (on ENST00000615277 / NM_001144382.2; = p.E98D on NM_015184.5) | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV67625821; called by muse, mutect2
- PPAT | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51705972; called by muse, mutect2, varscan2
- PRKACB | c.64A>G p.K22E | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.852); catalogued as rs1400460110; called by muse, mutect2
- PRKACB | c.687C>G p.I229M | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV65759281, COSV65759641; called by muse, mutect2
- PRKAR2A | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs147886817, COSV55551102; called by muse, mutect2, varscan2
- PRUNE2 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304996499; called by muse, mutect2, varscan2
- RBM48 | c.254A>C p.D85A | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.257); catalogued as rs1382719655; called by muse, mutect2, varscan2
- RIF1 | c.4247G>T p.R1416L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54614942, COSV54626490; called by muse, mutect2, varscan2
- RSPO4 | c.224C>A p.P75H | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1415219174, COSV54081114; called by muse, mutect2, varscan2
- RYR2 | c.12045A>T p.K4015N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV63667138; called by muse, mutect2, varscan2
- SH3BP5L | c.829G>T p.G277W | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs1401465643, COSV63538925; called by muse, mutect2, varscan2
- SIGLEC10 | c.1889C>T p.S630F | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV104411552; called by muse, mutect2, varscan2
- SLC5A9 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753658145; called by muse, mutect2, varscan2
- SLC6A12 | c.472A>G p.N158D | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as rs144464466; called by muse, mutect2, varscan2
- TGFBR2 | c.151T>C p.C51R | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559456531; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TLN2 | c.4117G>A p.E1373K | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as rs777291481; called by muse, mutect2, varscan2
- TNC | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV60792106; called by muse, mutect2, varscan2
- TRAJ16 | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 5/9 reads (56%) | catalogued as rs1412064322; called by muse, mutect2, varscan2
- TRIM42 | c.1345C>A p.L449M | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99648070; called by muse, mutect2, varscan2
- TTLL9 | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1177975181, COSV100206763; called by muse, mutect2, varscan2
- UNC5D | c.2174C>T p.S725L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99777675; called by muse, mutect2, varscan2
- WHRN | c.2234G>T p.R745L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs555619169, CM1411371, COSV54333761; called by muse, mutect2, varscan2
- XYLT1 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs771239606; called by muse, mutect2, varscan2
- ACSS1 | c.1352T>A p.I451N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ADAMTSL4 | c.2432T>C p.V811A | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AKAP4 | c.2305A>T p.S769C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ALPK2 | c.3284T>A p.F1095Y | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- ANP32D | c.149_150insA p.N51Qfs*17 | Frame Shift Ins (INS) | VAF 42/212 reads (20%) | called by mutect2, pindel*, varscan2
- ANXA7 | c.235G>T p.G79W | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- ATR | c.955A>T p.N319Y | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- BNIP5 | c.1748G>T p.R583L | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- C1orf141 | c.486T>A p.S162R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CCDC142 | c.1210G>C p.D404H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- CCDC172 | c.719C>A p.T240K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- CCDC178 | c.2248G>T p.A750S (on ENST00000383096 / NM_001105528.3; = p.A712S on NM_198995.3) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2
- CHD3 | c.2050C>T p.R684* | Nonsense Mutation (SNP) | VAF 54/152 reads (36%) | called by muse, mutect2, varscan2
- CNR1 | c.955A>T p.I319F | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- COL4A1 | c.4303G>T p.G1435W | Missense Mutation (SNP) | VAF 113/285 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- COL5A2 | c.1235C>A p.P412Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2
- COL7A1 | c.7456C>T p.P2486S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- COPB1 | c.1630G>T p.G544* | Nonsense Mutation (SNP) | VAF 23/169 reads (14%) | called by muse, mutect2, varscan2
- CPS1 | c.600G>C p.L200F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CYB5R2 | c.127del p.D43Tfs*4 | Frame Shift Del (DEL) | VAF 14/67 reads (21%) | called by mutect2, pindel, varscan2
- DEFB136 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- DENND2C | c.1436A>T p.E479V (on ENST00000393274 / NM_001256404.2; = p.E422V on NM_198459.4) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- DENND5B | c.285A>C p.K95N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- DIS3L2 | c.985A>T p.I329F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- DMKN | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- DNASE2B | c.968G>C p.G323A | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSG1 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DST | c.18292G>C p.E6098Q (on ENST00000361203 / NM_001374722.1; = p.E3795Q on NM_015548.5) | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EDAR | c.1127A>C p.H376P | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EHMT1 | c.2594A>T p.D865V | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- EP400 | c.3612C>G p.S1204R | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM214B | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- FGD3 | c.1174C>T p.L392F | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- FIZ1 | c.119G>C p.R40P | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- FRMD1 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- GALNT12 | c.1180C>G p.L394V | Missense Mutation (SNP) | VAF 82/281 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GPANK1 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIK3 | c.1184T>A p.I395N | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- HSD17B7 | c.690G>T p.L230F | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- IDH3G | c.776A>T p.Q259L | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- IGDCC3 | c.407C>A p.A136E | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- INAVA | c.1300C>A p.P434T | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- INHBA | c.845A>G p.D282G | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRAK3 | c.377del p.F126Sfs*34 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- ISL1 | c.467T>A p.L156Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- IWS1 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- KCNJ3 | c.750A>T p.E250D | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KCTD19 | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LACC1 | c.468A>T p.E156D | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRC20 | c.529G>T p.E177* (on ENST00000355790 / NM_207119.3; = p.E121* on NM_018205.4) | Nonsense Mutation (SNP) | VAF 19/115 reads (17%) | called by muse, mutect2, varscan2
- LRRK2 | c.7483G>T p.V2495F | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- MAGEA10 | c.592G>T p.G198C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MRO | c.743T>G p.L248R | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC16 | c.10523A>T p.D3508V | Missense Mutation (SNP) | VAF 90/248 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- NAP1L2 | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 55/142 reads (39%) | called by muse, mutect2, varscan2
- NEUROD4 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEUROD6 | c.734A>G p.E245G | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NINL | c.708+1G>T p.X236_splice | Splice Site (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- NRP2 | c.883G>T p.A295S | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NXPE4 | c.1243T>A p.Y415N (on ENST00000375478 / NM_001077639.2; = p.Y131N on NM_017678.3) | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- OR10Q1 | c.727T>C p.F243L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- OR5D14 | c.917T>G p.L306* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- OR5J2 | c.400G>C p.V134L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PANX1 | c.269A>G p.Q90R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- PCLO | c.4421A>G p.E1474G | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PHKA2 | c.2333A>G p.D778G | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PNCK | c.764C>A p.P255H (on ENST00000340888 / NM_001366975.1; = p.P338H on NM_001039582.3) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- POTEE | c.1687G>T p.G563C | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- PPP2R5D | c.1250A>T p.Q417L | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PTER | c.312C>A p.S104R | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RASGRF2 | c.1100A>C p.E367A | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- RHPN2 | c.304C>G p.Q102E | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- RIMBP2 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- ROR1 | c.191T>A p.M64K | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2
- RXRG | c.239C>A p.P80H | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SAAL1 | c.447C>G p.D149E | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2
- SEC63 | c.781A>G p.N261D | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- SEMA3A | c.104C>G p.S35C | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SERPINA11 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 76/211 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- SGSM1 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 16/105 reads (15%) | called by muse, mutect2, varscan2
- SLC40A1 | c.953A>G p.Y318C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC5A8 | c.1018C>G p.L340V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLIT3 | c.767T>A p.V256E | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SNU13 | c.4-1G>C p.X2_splice | Splice Site (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- SPAG17 | c.233A>G p.N78S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SPAM1 | c.1267C>A p.L423I | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TBXA2R | c.80C>G p.S27W | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM175 | c.708C>A p.G236= | Splice Region (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- TMEM190 | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TP53 | c.104dup p.L35Ffs*8 | Frame Shift Ins (INS) | VAF 132/460 reads (29%) | called by mutect2, pindel, varscan2
- TTN | c.90902T>C p.V30301A (on ENST00000591111; = p.V22877A on NM_003319.4) | Missense Mutation (SNP) | VAF 25/89 reads (28%) | PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TTN | c.30318del p.V10107Lfs*2 (on ENST00000591111; = p.V9180Lfs*2 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- UBOX5 | c.1394C>A p.S465Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- USP19 | c.920G>T p.C307F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- VDR | c.881A>T p.K294M | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- XIRP2 | c.5556G>T p.K1852N (on ENST00000628543; = p.K2027N on NM_152381.6) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ZBED9 | c.1357A>G p.I453V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ZNF483 | c.1718A>G p.H573R | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF536 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 34/90 reads (38%) | called by muse, mutect2, varscan2
- ZNF709 | c.759A>C p.E253D | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by mutect2, varscan2
- ADGRG4 | c.6183T>C p.S2061= | Silent (SNP) | VAF 60/174 reads (34%) | called by muse, mutect2, varscan2
- ALK | c.780C>T p.S260= | Silent (SNP) | VAF 29/82 reads (35%) | called by muse, mutect2, varscan2
- AMER3 | c.24C>T p.T8= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs1302790283, COSV100366013; called by muse, mutect2
- BARHL1 | c.843C>A p.R281= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs1457935112; called by muse, mutect2, varscan2
- CCDC172 | c.720A>G p.T240= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- CDH18 | c.951A>T p.S317= | Silent (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- COL27A1 | c.1824C>A p.G608= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs1157450547; called by muse, mutect2, varscan2
- CPN1 | c.498C>A p.L166= | Silent (SNP) | VAF 32/76 reads (42%) | called by muse, mutect2, varscan2
- DSG2 | c.2136C>T p.S712= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as rs762885119; called by muse, mutect2, varscan2
- EBF2 | c.219C>A p.L73= | Silent (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2
- FBXO25 | c.960T>C p.C320= (on ENST00000382824 / NM_183421.2; = p.C253= on NM_012173.3) | Silent (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- GABRQ | c.1080C>A p.R360= | Silent (SNP) | VAF 24/87 reads (28%) | called by muse, mutect2, varscan2
- GDF3 | c.315G>A p.L105= | Silent (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- GRIN2B | c.2968C>A p.R990= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs1260906966, COSV74204953; called by muse, mutect2, varscan2
- HDGFL1 | c.99C>T p.T33= | Silent (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- IGLC2 | c.309A>G p.T103= | Silent (SNP) | VAF 14/202 reads (7%) | called by muse, mutect2
- INAVA | c.1299G>A p.V433= | Silent (SNP) | VAF 31/130 reads (24%) | catalogued as COSV100950095; called by muse, mutect2, varscan2
- LHCGR | c.1371C>A p.L457= | Silent (SNP) | VAF 40/163 reads (25%) | catalogued as rs1308737348; called by muse, mutect2, varscan2
- MAGEA3 | c.654G>A p.E218= | Silent (SNP) | VAF 41/158 reads (26%) | called by muse, mutect2, varscan2
- MPP1 | c.1263C>A p.A421= | Silent (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- MYH13 | c.5430G>A p.K1810= | Silent (SNP) | VAF 61/228 reads (27%) | catalogued as rs757529882, COSV52822762; called by muse, mutect2, varscan2
- MYH6 | c.4158G>A p.E1386= | Silent (SNP) | VAF 33/112 reads (29%) | catalogued as COSV100676779; called by muse, mutect2, varscan2
- NNMT | c.558A>T p.L186= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100248839; called by muse, mutect2, varscan2
- NRP2 | c.882T>C p.S294= | Silent (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- NUP35 | c.558T>G p.A186= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, varscan2
- OPN1LW | c.969C>A p.V323= | Silent (SNP) | VAF 37/161 reads (23%) | called by muse, mutect2, varscan2
- OR11H1 | c.432C>G p.L144= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs1235632803, COSV99422034; called by mutect2, varscan2
- OR11L1 | c.615C>A p.A205= | Silent (SNP) | VAF 40/169 reads (24%) | catalogued as rs543584598, COSV63314688; called by muse, mutect2, varscan2
- OR4K17 | c.450C>A p.L150= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV59647753; called by muse, mutect2, varscan2
- OR5D18 | c.204C>G p.S68= | Silent (SNP) | VAF 47/187 reads (25%) | catalogued as COSV61738674; called by muse, mutect2, varscan2
- OR5M11 | c.18C>A p.G6= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV101602030; called by muse, varscan2
- OR8D2 | c.592C>T p.L198= | Silent (SNP) | VAF 32/120 reads (27%) | called by muse, mutect2, varscan2
- OTUD7B | c.111C>T p.A37= | Silent (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- PCDH15 | c.5856T>G p.S1952= | Silent (SNP) | VAF 36/57 reads (63%) | catalogued as COSV57287505; called by muse, mutect2, varscan2
- POPDC3 | c.504T>C p.D168= | Silent (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- PPAT | c.111C>G p.L37= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs754936603; called by muse, mutect2
- PRAME | c.678C>A p.I226= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs1294632054; called by muse, mutect2, varscan2
- PRMT6 | c.750G>T p.P250= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs1339721665; called by muse, mutect2, varscan2
- PSG5 | c.450C>T p.Y150= | Silent (SNP) | VAF 64/262 reads (24%) | called by muse, mutect2, varscan2
- RAB11FIP2 | c.276G>T p.V92= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV62924799; called by muse, mutect2, varscan2
- RGS22 | c.681A>G p.V227= | Silent (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- SELL | c.501C>G p.L167= (on ENST00000650983; = p.L154= on NM_000655.5) | Silent (SNP) | VAF 35/254 reads (14%) | called by muse, mutect2, varscan2
- SEMG1 | c.195T>C p.I65= | Silent (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- SERPINA11 | c.360G>T p.R120= | Silent (SNP) | VAF 75/211 reads (36%) | called by muse, mutect2, varscan2
- SGTB | c.654G>A p.L218= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- SLITRK3 | c.1494A>G p.A498= | Silent (SNP) | VAF 14/93 reads (15%) | called by muse, mutect2, varscan2
- SPEG | c.8505C>G p.L2835= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2
- THBS4 | c.1728A>G p.K576= | Silent (SNP) | VAF 61/193 reads (32%) | catalogued as rs371433798; called by muse, mutect2, varscan2
- TRAPPC1 | c.210A>G p.K70= | Silent (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- TTN | c.87075C>A p.A29025= (on ENST00000591111; = p.A21601= on NM_003319.4) | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs1160773007; called by muse, mutect2, varscan2
- UNC13A | c.102G>C p.T34= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs778802723; called by muse, mutect2, varscan2
- UPF2 | c.1509A>T p.A503= | Silent (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2
- VPS13D | c.12861G>A p.L4287= | Silent (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- ZNF831 | c.3525C>A p.P1175= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV64038436; called by muse, mutect2, varscan2
- ZNF839 | c.574C>T p.L192= (on ENST00000558850 / NM_001267827.1; = p.L308= on NM_018335.5) | Silent (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- ZNRF4 | c.249C>G p.V83= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV55776258; called by muse, mutect2, varscan2
- ZSWIM3 | c.939C>T p.L313= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs745702737; called by muse, mutect2, varscan2
- DKC1 | c.771+146A>T | Intron (SNP) | VAF 20/90 reads (22%) | called by muse, mutect2, varscan2
- FMN1 | c.2044-1901del | Intron (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- IKBIP | c.297+8097G>C | Intron (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- LINC01098 | n.775del | RNA (DEL) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- MIR891B | n.74A>G | RNA (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792518 G>T | 3'Flank (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
